Somatic mutation profile of tumor specimen TCGA-J9-A8CL-01A (aliquot TCGA-J9-A8CL-01A-11D-A34U-08) from TCGA case TCGA-J9-A8CL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.1 years (24,145 days).
Specimen TCGA-J9-A8CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 693acdf0-a6bb-45ab-9650-94f41ed08fbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A8CL-10A (Blood Derived Normal), aliquot TCGA-J9-A8CL-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b65b23c2-949c-43ab-99e8-255ca998f877

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 32, Silent 17, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS1 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs919807545, COSV100053955; called by muse, mutect2, varscan2
- ADAM20 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs529674678, COSV56454605; called by muse, mutect2, varscan2
- ADAMTS10 | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV54351845; called by muse, mutect2, varscan2
- CACNA2D1 | c.652T>G p.Y218D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100667048; called by muse, mutect2, varscan2
- CARD9 | c.710C>G p.A237G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as COSV100047582; called by muse, mutect2
- CBLIF | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99951053; called by muse, mutect2, varscan2
- CD1C | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100939429, COSV63807062; called by muse, mutect2, varscan2
- DOCK10 | c.4510C>T p.Q1504* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99290955; called by muse, mutect2
- DPPA5 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV100951516; called by muse, mutect2, varscan2
- EDIL3 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678447; called by muse, mutect2, varscan2
- EEF1AKNMT | c.442C>T p.R148C (on ENST00000361735 / NM_015935.5; = p.R62C on NM_014955.3) | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530716487, COSV100675985; called by muse, mutect2, varscan2
- GABRB3 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs777756010, COSV100161177; called by muse, mutect2, varscan2
- GRIN1 | c.878A>T p.H293L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV100160601; called by muse, mutect2, varscan2
- IFI16 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV55541234; called by muse, mutect2, varscan2
- IGLC2 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs371508809; called by muse, mutect2, varscan2
- KCNJ10 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.082); catalogued as rs200054482, COSV100927944; called by muse, mutect2, varscan2
- MFSD9 | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.054); catalogued as COSV99302253; called by muse, mutect2, varscan2
- MYH6 | c.5712G>C p.E1904D | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100198157, COSV100198216; called by muse, mutect2, varscan2
- NCSTN | c.689G>C p.C230S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99667468; called by muse, mutect2, varscan2
- NDUFS2 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV100917523; called by muse, mutect2, varscan2
- NETO1 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100199371; called by muse, mutect2, varscan2
- OR10J3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs867791135, COSV59953822; called by muse, mutect2, varscan2
- PBX3 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs1176754546, COSV100655552; called by muse, mutect2, varscan2
- PCDHGA9 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV53959476, COSV99543997; called by muse, mutect2, varscan2
- PIK3CA | c.1421A>C p.E474A | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV99841779; called by muse, mutect2, varscan2
- PKHD1L1 | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 23/429 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.153); catalogued as COSV101006637, COSV65756865; called by muse, mutect2
- PKNOX2 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.696); catalogued as COSV100021591; called by muse, mutect2, varscan2
- RETREG2 | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99811659; called by muse, mutect2, varscan2
- SEMA5B | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs763197088, COSV99530510; called by mutect2, varscan2
- SUOX | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99907175; called by muse, mutect2, varscan2
- SYNE1 | c.19198C>T p.R6400C (on ENST00000367255 / NM_182961.4; = p.R6329C on NM_033071.3) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as rs770043769, COSV54934435; called by muse, mutect2, varscan2
- TLK1 | c.1223G>C p.G408A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.125); catalogued as COSV100688656; called by muse, mutect2
- TTN | c.40769T>C p.V13590A (on ENST00000591111; = p.V6166A on NM_003319.4) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | PolyPhen benign (0.122); catalogued as COSV100624059; called by muse, mutect2, varscan2
- VAV3 | c.1731+1G>A p.X577_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100580202; called by muse, mutect2, varscan2
- ZNF148 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100642163; called by muse, mutect2, varscan2
- ZNF99 | c.1558C>A p.H520N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV101233912; called by muse, mutect2, varscan2
- ALDH6A1 | c.630A>G p.P210= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs904937692, COSV100620948; called by muse, mutect2, varscan2
- ASTE1 | c.817C>T p.L273= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99393949; called by muse, mutect2, varscan2
- BFSP1 | c.783C>T p.D261= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as rs370330055; called by muse, mutect2, varscan2
- BRD1 | c.195C>T p.L65= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs1327433476, COSV99350126; called by muse, mutect2, varscan2
- DOCK11 | c.2856A>G p.L952= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV99354444; called by muse, mutect2, varscan2
- DRP2 | c.2295G>A p.R765= | Silent (SNP) | VAF 43/67 reads (64%) | catalogued as COSV100872020, COSV65810693; called by muse, mutect2, varscan2
- E4F1 | c.1623C>T p.H541= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100065991; called by muse, mutect2, varscan2
- GRM8 | c.2487T>A p.S829= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV100285050; called by muse, mutect2, varscan2
- ITGAD | c.381G>T p.L127= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101210362; called by muse, mutect2, varscan2
- KALRN | c.5856G>T p.V1952= (on ENST00000360013 / NM_001024660.4; = p.V255= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV52256887; called by muse, mutect2, varscan2
- KDM2A | c.813G>A p.K271= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV101284669; called by muse, mutect2
- KMT2C | c.11619G>A p.E3873= | Silent (SNP) | VAF 58/300 reads (19%) | catalogued as rs746396460, COSV100075118; called by muse, mutect2, varscan2
- MYO7B | c.879C>T p.N293= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs369461546; called by muse, mutect2, varscan2
- MYRIP | c.1365G>A p.S455= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs146724522; called by muse, mutect2, varscan2
- SPHKAP | c.318C>T p.N106= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs777500302, COSV60871654; called by muse, mutect2, varscan2
- THEMIS | c.1674G>A p.P558= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as rs866930287, COSV64069210; called by muse, mutect2, varscan2
- TRIM60 | c.1311C>G p.L437= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100594085; called by muse, mutect2, varscan2
